Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4696, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4696-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, POORLY DIFFERENTIATED, WITH CHROMOPHOBE CELL AND SARCOMATOID TYPES.
- B. FUHRMAN NUCLEAR GRADE 4 OF 4.
- C. THE TUMOR MEASURES 17.0 CM IN GREATEST DIMENSION.
- D. THE PATTERN OF GROWTH IS PREDOMINANTLY SOLID.
- E. NO INVASION OF RENAL VEIN IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- G. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN THE GEROTA'S FASCIA.
- H. TNM STAGING = pT3a, NX, MX.
- I. TNM HISTOPATHOLOGIC GRADING = G3.
- J. NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- K. THE ADRENAL GLAND IS UNREMARKABLE.

COMMENT:

The tumor is composed of two histological patterns: the typical chromophobe cell type renal cell adenocarcinoma is juxtaposed to a high-grade sarcomatoid pattern. The chromophobe cell and the sarcomatoid areas occupies approximately 40% and 60% of the total tumor volume, respectively. Immunostaining is performed and the results will be reported in an addendum to confirm the chromophobe component.

Addendum

Special and immunostaining reveal that the chromophobe component of the tumor is positive for Hale's colloid iron, EMA and focally for CAM 5.2. Our diagnosis is not changed by these findings. Therefore, the previously listed final diagnosis (see below) should be considered our final report. With this report, our study of this case is now completed. Thank you for involving us in the care of this patient.

Source: NCI Genomic Data Commons file 9539bea3-84b7-4d4e-b2cf-872e5c589c9b (TCGA-B0-4696.79CC1DCF-7796-4D7D-A16B-062B2FD872B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).